Gene-level copy-number profile of tumor specimen TCGA-DD-AAVW-01A from TCGA case TCGA-DD-AAVW, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 35.6 years (12,986 days).
Specimen TCGA-DD-AAVW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.52e80f07-295b-484b-b1b5-5136f1506762.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AAVW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cd998896-24c7-42b4-81ae-610ad7e85a93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 51; copy number 1: 13,143; copy number 2: 37,567; copy number 3: 7,296; copy number 4: 470; copy number 5: 35; copy number 6: 1,251.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AAVW-01A-11D-A40Q-01): tumor purity 0.57, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:170,814,339–171,059,163, 4 genes (within-gene range 0–1): AC097486.1, RNU6ATAC13P, AC034159.2, LINC02431.
- chr16:86,081,409–86,158,798, 2 genes: AC135012.1, AC135012.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,286 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:2,045,046–6,257,537, 35 genes, copy number 5 (within-gene range 3–5): MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1, CSMD1, AC026991.1, AC026991.2, RNA5SP251, AC027251.1, AC010941.1, AC022068.1, PAICSP4, AC019176.1, AC019176.2, SNORA70, RN7SL318P, AC007718.1, AC091193.1, RPL23AP54, AC004944.1, AC084768.1, AC084768.2, AC087369.1, AC087369.2, RN7SKP159, AC079054.1, AC009435.1.
- chr8:51,319,577–139,704,109, 1,249 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:139,911,238–139,933,942, 2 genes, copy number 6: AC021744.1, C8orf17.

Autosomal genes at a single copy (total copy number 1): 10,801. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
